Somatic mutation profile of tumor specimen TCGA-BQ-5878-01A (aliquot TCGA-BQ-5878-01A-11D-1589-08) from TCGA case TCGA-BQ-5878, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 79.4 years (29,010 days).
Specimen TCGA-BQ-5878-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ef79234-bb45-4c62-99a8-83138c7c0e51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-5878-11A (Solid Tissue Normal), aliquot TCGA-BQ-5878-11A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/352f4df6-d2dc-435a-9e02-da6d68718e98

The open-access MAF lists 102 somatic variants for this specimen: 73 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 26, Frame Shift Del 7, Nonsense Mutation 2, Splice Region 2, Splice Site 2, Frame Shift Ins 2, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRM | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65754795; called by muse, mutect2, varscan2
- AK7 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773352505, COSV50873548; called by muse, mutect2, varscan2
- ANK1 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV55884535; called by muse, mutect2, varscan2
- ARID1A | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as COSV61372729, COSV61385466; called by muse, mutect2, varscan2
- ASIC5 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV73332795; called by muse, mutect2, varscan2
- CCN2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959044702, COSV63466776; called by muse, mutect2, varscan2
- CIT | c.2842G>A p.D948N | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV55872464; called by muse, mutect2, varscan2
- CRYBG1 | c.3866A>T p.E1289V | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV64812750; called by muse, mutect2, varscan2
- CYP2A13 | c.471C>G p.I157M | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as COSV57837078, COSV57838456; called by muse, mutect2, varscan2
- DISP3 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV53829806; called by muse, mutect2
- DLG5 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs762501307, COSV64948468; called by muse, mutect2, varscan2
- DMWD | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV52179192; called by muse, mutect2, varscan2
- DSC3 | c.2332del p.T778Pfs*4 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | catalogued as COSV64574035, COSV64574189; called by mutect2, pindel, varscan2
- ECSIT | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV52939790; called by muse, mutect2, varscan2
- ELP4 | c.314A>G p.E105G | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63353947; called by muse, mutect2, varscan2
- ESX1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs1456645849, COSV65424550; called by muse, mutect2, varscan2
- F13A1 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396702202, CM023371, CM993150, COSV53560635; called by muse, mutect2, varscan2
- FPR2 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60673203; called by muse, mutect2, varscan2
- GFRAL | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231832, COSV61231991; called by muse, mutect2, varscan2
- GPKOW | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.446); catalogued as COSV50243186; called by muse, mutect2, varscan2
- HMGB2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs768983347, COSV56633784; called by muse, mutect2, varscan2
- HRC | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs1043250044, COSV53256962; called by muse, mutect2, varscan2
- KCNJ16 | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV52254443; called by muse, mutect2, varscan2
- L1TD1 | c.379G>C p.G127R | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.059); catalogued as COSV63133618; called by muse, mutect2, varscan2
- LAIR2 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 73/208 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.597); catalogued as COSV56621758; called by muse, mutect2, varscan2
- LEXM | c.122T>C p.V41A | Missense Mutation (SNP) | VAF 90/218 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.72); catalogued as COSV64023166; called by muse, mutect2, varscan2
- LIPI | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs758215638, COSV60712653; called by muse, mutect2, varscan2
- MAP2K5 | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51617246; called by muse, mutect2
- MAPK10 | c.1072A>G p.K358E (on ENST00000359221 / NM_001351625.2; = p.K396E on NM_002753.5) | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs895854132, COSV60385016; called by muse, mutect2, varscan2
- MUC16 | c.4309G>A p.D1437N | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV67473907; called by muse, mutect2
- MYO18A | c.3490T>A p.C1164S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV62868378; called by muse, mutect2, varscan2
- NANOG | c.45A>C p.E15D | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV57551651; called by muse, mutect2, varscan2
- NEK7 | c.747G>C p.K249N | Missense Mutation (SNP) | VAF 77/170 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV66315293; called by muse, mutect2, varscan2
- NFKB2 | c.2314G>C p.D772H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV50047491; called by muse, mutect2, varscan2
- NOTCH3 | c.4364A>G p.N1455S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV54637950; called by muse, mutect2, varscan2
- NTRK1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100693370, COSV62326279; called by muse, mutect2, varscan2
- OASL | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV57478795; called by muse, mutect2, varscan2
- OR4A16 | c.832C>A p.L278I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as rs749090450, COSV59043635; called by muse, mutect2, varscan2
- OR51B6 | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66513282; called by muse, mutect2, varscan2
- PCDHB15 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs564192004, COSV51008289; called by muse, mutect2
- POM121 | c.2191A>G p.I731V (on ENST00000434423; = p.I466V on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1408887104, COSV57517631; called by muse, mutect2, varscan2
- PPP1R9A | c.2785C>A p.P929T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV56897143; called by muse, mutect2, varscan2
- PRLR | c.680C>G p.P227R | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51496881, COSV99184763; called by muse, mutect2, varscan2
- RPL26L1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV54199775; called by muse, mutect2
- SASH1 | c.630C>G p.L210= | Splice Region (SNP) | VAF 59/169 reads (35%) | catalogued as COSV66562677; called by muse, mutect2, varscan2
- SELENOP | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as COSV62792891; called by muse, mutect2, varscan2
- SLC13A3 | c.1317G>T p.M439I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV51717488, COSV51720853; called by muse, mutect2, varscan2
- SLC35G5 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1245674039, COSV55310221; called by muse, mutect2, varscan2
- SLC45A2 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56872653; called by muse, mutect2, varscan2
- SOS2 | c.2927C>T p.P976L | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV53569096; called by muse, mutect2, varscan2
- SPAG6 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as COSV57621245; called by muse, mutect2, varscan2
- SPIN1 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65499775; called by muse, mutect2
- SPOCK1 | c.705C>T p.G235= | Splice Region (SNP) | VAF 42/108 reads (39%) | catalogued as COSV56452922; called by muse, mutect2, varscan2
- SRRM2 | c.5617C>G p.H1873D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV57075083; called by muse, mutect2, varscan2
- SRRM2 | c.7667C>G p.S2556C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51940991; called by muse, mutect2, varscan2
- TNRC18 | c.8138C>T p.S2713L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1423202870, COSV60308047; called by muse, mutect2, varscan2
- TNS3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV60792940; called by muse, mutect2, varscan2
- TTN | c.95080G>A p.E31694K (on ENST00000591111; = p.E24270K on NM_003319.4) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | PolyPhen probably damaging (0.994); catalogued as COSV60044827; called by muse, mutect2, varscan2
- TUB | c.1113C>G p.C371W (on ENST00000299506 / NM_177972.3; = p.C426W on NM_003320.4) | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104397704, COSV55108509; called by muse, mutect2, varscan2
- UNC13A | c.2918T>A p.L973H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53198762; called by muse, mutect2, varscan2
- YES1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV58850802; called by muse, mutect2, varscan2
- ZFHX3 | c.7847G>A p.R2616K | Missense Mutation (SNP) | VAF 177/428 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV51722705; called by muse, mutect2, varscan2
- ZNF318 | c.2770+1del p.X924_splice | Splice Site (DEL) | VAF 28/75 reads (37%) | catalogued as rs750618782, COSV58930337; called by mutect2, pindel, varscan2
- ZNF831 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375833789; called by muse, mutect2, varscan2
- KMT2D | c.7343del p.D2448Afs*37 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- NAPSA | c.1066del p.S356Pfs*35 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- PCSK4 | c.213del p.H72Tfs*12 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.3864_3865insA p.S1289Ifs*18 | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- POMGNT1 | c.173_174del p.I58Tfs*9 | Frame Shift Del (DEL) | VAF 89/261 reads (34%) | called by mutect2, pindel, varscan2
- RAB6A | c.456del p.F152Lfs*12 | Frame Shift Del (DEL) | VAF 45/127 reads (35%) | called by mutect2, pindel, varscan2
- SLC23A1 | c.926-24_928del p.X309_splice | Splice Site (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel
- TENM3 | c.3566_3572del p.G1189Afs*13 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- USP28 | c.2205_2206insCA p.S736Hfs*6 | Frame Shift Ins (INS) | VAF 52/128 reads (41%) | called by mutect2, pindel*, varscan2
- ABCA12 | c.5322T>C p.Y1774= (on ENST00000272895 / NM_173076.3; = p.Y1456= on NM_015657.3) | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs774575248, COSV55963139; called by muse, mutect2, varscan2
- ASIC5 | c.933C>T p.S311= | Silent (SNP) | VAF 55/103 reads (53%) | catalogued as COSV73332794; called by muse, mutect2, varscan2
- BRSK2 | c.816G>C p.G272= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs781213875, COSV57544323; called by muse, mutect2
- BSCL2 | c.1017G>A p.E339= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV54016188; called by muse, mutect2, varscan2
- C14orf93 | c.372T>G p.P124= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV54441352; called by muse, mutect2, varscan2
- CHD5 | c.1830C>T p.Y610= | Silent (SNP) | VAF 76/150 reads (51%) | catalogued as rs779029688, COSV52417237; called by muse, mutect2, varscan2
- CPO | c.933G>C p.L311= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as COSV55940145; called by muse, mutect2, varscan2
- EXOC3 | c.45G>A p.R15= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV59267273; called by muse, mutect2, varscan2
- F8 | c.6066C>A p.G2022= | Silent (SNP) | VAF 60/117 reads (51%) | catalogued as COSV64274745; called by muse, mutect2, varscan2
- GDF7 | c.1224C>T p.D408= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs376857749, COSV55347022; called by muse, mutect2, varscan2
- HOOK2 | c.1734G>A p.R578= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV53402687; called by muse, mutect2
- KDM3B | c.681T>C p.R227= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV58691802; called by muse, mutect2, varscan2
- LMTK2 | c.3783C>T p.I1261= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs150501122; called by muse, mutect2, varscan2
- LONP2 | c.2463T>C p.F821= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs747595818, COSV53523339; called by muse, mutect2, varscan2
- LRBA | c.1635T>A p.L545= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV63957302; called by muse, mutect2, varscan2
- MAGOHB | c.85C>A p.R29= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV57898632, COSV57899083; called by muse, mutect2
- OR52J3 | c.327C>T p.F109= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV66747200; called by muse, mutect2, varscan2
- PCDH15 | c.4380C>G p.L1460= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV57331347; called by muse, mutect2, varscan2
- PIP4K2A | c.69C>T p.F23= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs748177306, COSV64863669; called by muse, mutect2, varscan2
- PROCR | c.183A>T p.P61= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV53826066; called by muse, mutect2, varscan2
- PSD2 | c.1020C>T p.N340= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs142589356; called by muse, mutect2, varscan2
- RAD54L2 | c.4374C>T p.D1458= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs192987707; called by muse, mutect2, varscan2
- SLF2 | c.1041C>T p.S347= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV53275053; called by muse, mutect2, varscan2
- TMF1 | c.27C>T p.L9= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs1211187128, COSV62740751; called by muse, mutect2, varscan2
- TTN | c.58962G>A p.G19654= (on ENST00000591111; = p.G12230= on NM_003319.4) | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV60134344; called by muse, mutect2
- ZNF485 | c.1005C>T p.F335= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV62424554, COSV62425497; called by muse, mutect2, varscan2
- DEPDC5 | c.*728T>G | 3'UTR (SNP) | VAF 18/35 reads (51%) | catalogued as COSV56700643; called by muse, mutect2, varscan2
- GLRX2 | chr1:193105574 G>A | 5'Flank (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100814185; called by muse, mutect2, varscan2
- TSPAN6 | c.-1C>T | 5'UTR (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100885744; called by muse, mutect2
